Somatic mutation profile of tumor specimen 0DQMPN from CCDI case PBCEPF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Papillary carcinoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 17.0 years (6,212 days).
Specimen 0DQMPN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9402d73b-bcd9-46ca-aae1-7d7a62057c8c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQMQT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cc9ca180-8722-4567-9ba0-9883061e2628

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKAL1 | c.49G>T p.V17L | Missense Mutation (SNP) | VAF 279/946 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.134); catalogued as rs560146971, COSV51181467; called by muse, mutect2, varscan2
- PCDH11X | c.753G>C p.E251D | Missense Mutation (SNP) | VAF 132/780 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TRIM15 | c.580C>G p.L194V | Missense Mutation (SNP) | VAF 105/828 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 8/52 reads (15%) | called by muse, varscan2
- UGT2B4 | c.*10A>G | 3'UTR (SNP) | VAF 138/524 reads (26%) | catalogued as rs761549102; called by muse, mutect2, varscan2
